Surgical pathology report (de-identified scan), TCGA case TCGA-FE-A3PA, project TCGA-THCA (Thyroid Carcinoma), tissue source site Ohio State University, specimen TCGA-FE-A3PA-01A (Primary Tumor).

[page 1 of 2]
1

Print this Page

Sex

Specimen Description

THYROID, REG

procurement date:

Name: [REDACTED] Location: [REDACTED] Med Rec No.: [REDACTED] Pathology No.: [REDACTED]

Age/Sex: [REDACTED] Collect Date: [REDACTED] Accession Date: [REDACTED] Report Date: [REDACTED] Physician: [REDACTED]

Clinical History:

Papillary carcinoma of the thyroid; 3 CM left sided tumor

Surgical Pathology Report

DIAGNOSIS:

- A. Thyroid gland, excision:
- Papillary thyroid carcinoma
- Tumor size: Multinodular, approximately 4 cm in greatest dimension
- Tumor extent: Carcinoma invades the capsule, with focal extra-capsular extension
- Margins: Carcinoma is focally less than 0.05 cm from inked margin

COMMENTS:

Sections of the multinodular tumor show papillary thyroid carcinoma, predominantly the follicular variant. The frozen section diagnosis is confirmed.

MICROSCOPIC EXAMINATION:

A microscopic examination was performed.

INTRAOPERATIVE CONSULTATION:

- AF1. Total thyroid, excision: (FROZEN SECTION PERFORMED)
- Papillary carcinoma, predominant follicular variant
- [REDACTED] agrees

ICD-0-3
carcinoma, papillary, thyroid
Site: thyroid, NOS c73.9 8260/3

fw
2/5/12

GROSS DESCRIPTION:

The specimen is received in one container labeled with the patient's name, [REDACTED]

- A. The specimen is designated, "total thyroid" and consists of an unoriented 44 gram total thyroid that measures 6.0 x 5.5 x 3.0 cm. The external surface is multilobulated, smooth, and glistening. Cut sections of the gland reveal that one lobe is largely replaced by a 4 x 3 x 3 cm pale pink-tan, firm, multinodular tumor. The other lobe shows a 3.0 x 1.5 x 1.5 cm portion of granular beefy relatively normal thyroid parenchyma. No lymph nodes or parathyroid glands are identified grossly. One section of the thyroid has been submitted for frozen section examination. Frozen section tissue is resubmitted as received in cassette AF1. RS 9

AF1, frozen section residual; A1-A6, pale pink firm multinodular tumor

[page 2 of 2]
(presumably left lobe); A7-, ., relatively normal thyroid parenchyma
(presumably right lobe)

PROCEDURE CODE: STHR

TISSUE(S) SUBMITTED:

A: THYROID, REG

Electronically signed by: [REDACTED]

Top of Page

Source: NCI Genomic Data Commons file b88364d4-57b0-4dbc-bf4d-ff3df23c27fb (TCGA-FE-A3PA.7FA0F656-75E1-4D38-95C3-6E77F30AEADC.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).